Somatic mutation profile of tumor specimen TCGA-AR-A1AL-01A (aliquot TCGA-AR-A1AL-01A-21D-A12Q-09) from TCGA case TCGA-AR-A1AL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.3 years (22,023 days).
Specimen TCGA-AR-A1AL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f787be-8204-4614-8437-884773ae759d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AL-10A (Blood Derived Normal), aliquot TCGA-AR-A1AL-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da8d7222-5e31-4a0b-a602-f3a79ce2f824

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 97/403 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 51/296 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHCTF1 | c.1268A>C p.N423T (on ENST00000366508; = p.N397T on NM_015446.5) | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58252312; called by muse, mutect2, varscan2
- ARF1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs1419831068, COSV55255286; called by muse, mutect2, varscan2
- C4BPA | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 247/588 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV65536843; called by muse, mutect2, varscan2
- CALHM2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.509); catalogued as rs1312068082, COSV53296567; called by muse, mutect2, varscan2
- DLL4 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs777108179, COSV51064988; called by muse, mutect2, varscan2
- ETV1 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 75/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54146449; called by muse, mutect2, varscan2
- GIN1 | c.1124A>T p.K375I | Missense Mutation (SNP) | VAF 116/548 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67537328; called by muse, mutect2, varscan2
- HIVEP1 | c.7345T>C p.S2449P | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV65103273; called by muse, mutect2, varscan2
- IFT46 | c.362G>A p.R121H (on ENST00000264021 / NM_001168618.2; = p.R172H on NM_020153.3) | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs782623965, COSV50594718; called by muse, mutect2, varscan2
- INPP1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776864674, COSV100487160; called by muse, mutect2
- MOGS | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV51970554; called by muse, mutect2, varscan2
- PROSER1 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV61487141; called by muse, mutect2, varscan2
- RGMA | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.053); catalogued as rs376438901; called by muse, mutect2
- RPGRIP1L | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50910113, COSV50913573; called by muse, mutect2, varscan2
- RPRD1B | c.825_826del p.K275Nfs*51 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as COSV65033465; called by mutect2, pindel, varscan2
- SLC36A1 | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV99695488; called by muse, mutect2
- TAF1 | c.1693G>A p.G565R (on ENST00000373790 / NM_138923.4; = p.G586R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/577 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV52118502; called by muse, mutect2, varscan2
- TNRC6A | c.5350G>A p.V1784I | Missense Mutation (SNP) | VAF 100/567 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59367182; called by muse, mutect2, varscan2
- TOR1A | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV52213934; called by muse, mutect2, varscan2
- CDH1 | c.1513del p.I505Sfs*17 | Frame Shift Del (DEL) | VAF 36/163 reads (22%) | called by mutect2, pindel, varscan2
- ZNRF3 | c.1492G>T p.A498S (on ENST00000544604 / NM_001206998.2; = p.A398S on NM_032173.3) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2
- CASP8AP2 | c.1479T>C p.P493= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as COSV52748397; called by muse, mutect2, varscan2
- ENG | c.1443A>G p.P481= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV61228031; called by muse, mutect2, varscan2
- MTERF2 | c.144A>G p.T48= | Silent (SNP) | VAF 108/643 reads (17%) | catalogued as COSV53527966; called by muse, mutect2, varscan2
- SORBS1 | c.711G>T p.T237= (on ENST00000361941 / NM_001034954.2; = p.T205= on NM_015385.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99527767; called by muse, mutect2, varscan2
- TSPAN2 | c.141A>G p.S47= | Silent (SNP) | VAF 46/251 reads (18%) | catalogued as COSV65690255; called by muse, mutect2, varscan2
